Somatic mutation profile of cancer-model specimen HCM-CSHL-1265-C25-85A (3D Organoid; aliquot HCM-CSHL-1265-C25-85A-01D-A905-36), derived from the primary tumor of HCMI case HCM-CSHL-1265-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Carcinosarcoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 71.2 years (26,004 days).
Specimen HCM-CSHL-1265-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb7c7b6e-0fe5-4f68-a1ff-7008a4efa7e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-1265-C25-11A (Solid Tissue Normal), aliquot HCM-CSHL-1265-C25-11A-01D-A905-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8cdba1b-8fe1-477f-ad41-8773d02e1f50

The open-access MAF lists 51 somatic variants for this specimen: 36 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 14, Frame Shift Del 3, Nonsense Mutation 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.8488C>T p.R2830* | Nonsense Mutation (SNP) | VAF 832/1082 reads (77%) | catalogued as rs727503983, CM105465, COSV56427366; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 519/520 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.451C>A p.P151T | Missense Mutation (SNP) | VAF 1027/1028 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AMER3 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 536/1102 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as rs949105785, COSV58465006; called by muse, varscan2
- C20orf27 | c.475G>A p.A159T (on ENST00000379772 / NM_001258429.2; = p.A184T on NM_001039140.3) | Missense Mutation (SNP) | VAF 202/1543 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs747293739, COSV53923679; called by muse, mutect2, varscan2
- CHD5 | c.5746G>A p.A1916T | Missense Mutation (SNP) | VAF 382/611 reads (63%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); catalogued as rs759789009; called by muse, mutect2, varscan2
- CPED1 | c.2896T>C p.Y966H | Missense Mutation (SNP) | VAF 7/186 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV59998138; called by muse, mutect2
- DHCR7 | c.1405C>T p.R469C | Missense Mutation (SNP) | VAF 72/1000 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs148660993, CM154269; ClinVar: uncertain significance; called by muse, mutect2
- DNASE1L1 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 181/771 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1198800756; called by muse, mutect2, varscan2
- FAM135B | c.3233C>T p.S1078F | Missense Mutation (SNP) | VAF 220/965 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs771079943; called by muse, mutect2, varscan2
- HLA-DMA | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 552/1315 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs781137860; called by muse, varscan2
- MLLT11 | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 552/1116 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs749300187; called by muse, varscan2
- OBSCN | c.13675G>A p.V4559M | Missense Mutation (SNP) | VAF 695/1430 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368391837; called by muse, mutect2, varscan2
- OSBPL3 | c.403G>C p.D135H | Missense Mutation (SNP) | VAF 181/811 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs1452591190; called by muse, mutect2, varscan2
- OTUD7A | c.1343C>T p.T448M (on ENST00000307050 / NM_001382637.1; = p.T441M on NM_130901.3) | Missense Mutation (SNP) | VAF 224/1170 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs779792575, COSV61037466; called by muse, mutect2, varscan2
- PCDHA13 | c.1985C>T p.T662M | Missense Mutation (SNP) | VAF 220/914 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.966); catalogued as rs1356283866, COSV56477666, COSV99170418; called by muse, mutect2, varscan2
- PCDHA3 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 36/850 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100974220; called by muse, mutect2
- PLCL1 | c.1324G>A p.V442I | Missense Mutation (SNP) | VAF 247/949 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.05); catalogued as rs201197388; called by muse, mutect2, varscan2
- SCNN1G | c.1691G>A p.R564H | Missense Mutation (SNP) | VAF 276/1072 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs762732326, COSV55597490; called by muse, mutect2, varscan2
- SH2B1 | c.1864G>A p.V622I | Missense Mutation (SNP) | VAF 471/947 reads (50%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as rs143410496; called by muse, mutect2, varscan2
- TRMT61A | c.453C>G p.H151Q | Missense Mutation (SNP) | VAF 397/1266 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1203499344; called by muse, mutect2, varscan2
- VLDLR | c.211A>T p.T71S | Missense Mutation (SNP) | VAF 327/328 reads (100%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.891); catalogued as COSV66074182; called by muse, mutect2, varscan2
- ADD1 | c.616A>G p.I206V | Missense Mutation (SNP) | VAF 404/410 reads (99%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRL2 | c.3936C>A p.D1312E (on ENST00000370717 / NM_001366005.1; = p.D1256E on NM_012302.4) | Missense Mutation (SNP) | VAF 267/774 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CERS1 | c.509A>G p.D170G | Missense Mutation (SNP) | VAF 276/796 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DDC | c.899del p.N300Ifs*8 | Frame Shift Del (DEL) | VAF 394/913 reads (43%) | called by mutect2, pindel, varscan2
- HCFC1 | c.5533G>T p.V1845F | Missense Mutation (SNP) | VAF 425/875 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- HNRNPUL2 | c.1477del p.M493* | Frame Shift Del (DEL) | VAF 220/507 reads (43%) | called by mutect2, pindel, varscan2
- MAGEL2 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 245/772 reads (32%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- NES | c.388G>A p.V130M | Missense Mutation (SNP) | VAF 311/1227 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- NEXN | c.1696A>G p.M566V | Missense Mutation (SNP) | VAF 367/552 reads (66%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRPF40B | c.1291A>G p.T431A (on ENST00000380281; = p.T425A on NM_012272.3) | Missense Mutation (SNP) | VAF 197/911 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- RIC8A | c.1310_1311del p.E437Gfs*2 (on ENST00000526104 / NM_001286134.1; = p.E443Gfs*2 on NM_021932.5) | Frame Shift Del (DEL) | VAF 260/647 reads (40%) | called by pindel, varscan2
- TTYH2 | c.1314G>A p.W438* | Nonsense Mutation (SNP) | VAF 525/992 reads (53%) | called by muse, varscan2
- ZFP69B | c.1102T>C p.C368R | Missense Mutation (SNP) | VAF 249/802 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFR2 | c.1844C>G p.S615C | Missense Mutation (SNP) | VAF 724/1133 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, varscan2
- CFAP46 | c.1233G>A p.A411= | Silent (SNP) | VAF 228/1121 reads (20%) | catalogued as rs768406605, COSV63951800; called by muse, mutect2
- CFH | c.1140G>A p.S380= | Silent (SNP) | VAF 15/542 reads (3%) | catalogued as rs1273044132, COSV62777808; called by muse, mutect2
- CHD7 | c.8640G>A p.P2880= | Silent (SNP) | VAF 362/1370 reads (26%) | catalogued as rs374937585, COSV71110773; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CNR2 | c.153C>T p.N51= | Silent (SNP) | VAF 474/743 reads (64%) | catalogued as rs147653938; called by muse, varscan2
- FCSK | c.2136G>A p.P712= | Silent (SNP) | VAF 442/946 reads (47%) | catalogued as rs1047381765; called by muse, mutect2, varscan2
- ITPR3 | c.4177C>T p.L1393= | Silent (SNP) | VAF 409/805 reads (51%) | called by muse, mutect2, varscan2
- MCM10 | c.2583A>G p.L861= (on ENST00000484800 / NM_182751.3; = p.L860= on NM_018518.5) | Silent (SNP) | VAF 258/596 reads (43%) | called by muse, mutect2, varscan2
- PARG | c.1968C>T p.Y656= | Silent (SNP) | VAF 225/521 reads (43%) | called by muse, mutect2, varscan2
- SEPTIN12 | c.576G>A p.V192= | Silent (SNP) | VAF 480/984 reads (49%) | called by muse, mutect2, varscan2
- SERPINB4 | c.813T>C p.S271= | Silent (SNP) | VAF 408/410 reads (100%) | catalogued as rs1257227811; called by muse, mutect2, varscan2
- SI | c.3159C>T p.T1053= | Silent (SNP) | VAF 24/752 reads (3%) | catalogued as rs959072631; called by muse, mutect2
- UNCX | c.1527C>T p.C509= | Silent (SNP) | VAF 598/1180 reads (51%) | catalogued as rs943990338; called by muse, mutect2, varscan2
- UNKL | c.1927C>T p.L643= (on ENST00000389221 / NM_001372107.1; = p.L139= on NM_001276414.2) | Silent (SNP) | VAF 345/1161 reads (30%) | catalogued as rs1035581569; called by muse, mutect2, varscan2
- ZNF620 | c.9G>A p.Q3= | Silent (SNP) | VAF 344/656 reads (52%) | called by muse, mutect2, varscan2
- NPAP1L | n.198G>T | RNA (SNP) | VAF 188/414 reads (45%) | called by muse, mutect2, varscan2
